Somatic mutation profile of tumor specimen TCGA-AO-A03L-01A (aliquot TCGA-AO-A03L-01A-41W-A071-09) from TCGA case TCGA-AO-A03L, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 34.1 years (12,443 days).
Specimen TCGA-AO-A03L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56b7a3f8-6859-4682-89b5-efb6dde36b69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A03L-10A (Blood Derived Normal), aliquot TCGA-AO-A03L-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b8d4a9-f3a6-4687-8b6f-1b3d40afdbdc

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASMT | c.775G>C p.D259H (on ENST00000381229; = p.D287H on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67109600; called by muse, mutect2
- CBLB | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV51422488; called by muse, mutect2, varscan2
- DDX3X | c.422C>T p.P141L (on ENST00000399959; = p.P142L on NM_001356.5) | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV67863178, COSV67863939; called by muse, mutect2, varscan2
- GABRA1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs139793542, COSV99195723; called by muse, mutect2
- GOLGB1 | c.7829C>G p.S2610C | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV61462591; called by muse, mutect2, varscan2
- GRIA1 | c.2213G>C p.G738A | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53592043, COSV53602494; called by muse, mutect2
- IL1RAPL1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56242923; called by muse, mutect2, varscan2
- KLF11 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV59940120; called by muse, mutect2, varscan2
- MCOLN3 | c.984A>C p.E328D | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62013223; called by muse, mutect2, varscan2
- MECP2 | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57652194; called by muse, mutect2, varscan2
- MROH8 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs769537714, COSV54117943; called by muse, mutect2
- PRRX1 | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as CM143965, COSV53411595; called by muse, mutect2, varscan2
- PTPRB | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51726383; called by muse, mutect2, varscan2
- PYHIN1 | c.956A>T p.K319I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63721637; called by muse, mutect2, varscan2
- RASAL2 | c.1974G>T p.L658F | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100862438; called by muse, mutect2
- SERPINB8 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54639203; called by muse, mutect2, varscan2
- SETD7 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56799544; called by muse, mutect2, varscan2
- UBN1 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as rs760297239, COSV52166297; called by muse, mutect2, varscan2
- XRN2 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65868379; called by muse, mutect2, varscan2
- COL7A1 | c.2890G>T p.V964L | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- ELL2 | c.1377_1378del p.H459Qfs*8 | Frame Shift Del (DEL) | VAF 28/298 reads (9%) | called by pindel, varscan2
- SPDYE3 | c.1592T>A p.I531N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESX1 | c.69C>T p.I23= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV65424020; called by muse, mutect2, varscan2
- PAK5 | c.2094A>G p.P698= | Silent (SNP) | VAF 90/295 reads (31%) | catalogued as rs781145887, COSV62022692; called by muse, mutect2, varscan2
- THOC2 | c.2568G>T p.V856= | Silent (SNP) | VAF 27/289 reads (9%) | catalogued as COSV55541744; called by muse, mutect2
